Somatic mutation profile of tumor specimen TCGA-92-7340-01D (aliquot TCGA-92-7340-01D-01D-A38P-08) from TCGA case TCGA-92-7340, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIA; Age at diagnosis: 45.0 years (16,447 days).
Specimen TCGA-92-7340-01D: Sample type: FFPE Scrolls; Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c8eee648-8fc8-4cd7-97b7-eaab2a8b4522.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-92-7340-10A (Blood Derived Normal), aliquot TCGA-92-7340-10A-01D-2042-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1f1aea18-3f30-4751-bb5e-e6994c2c0acc

The open-access MAF lists 330 somatic variants for this specimen: 243 protein-altering or splice-affecting, 80 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 217, Silent 80, Nonsense Mutation 10, Frame Shift Del 6, Splice Site 4, Splice Region 4, RNA 3, Intron 3, Frame Shift Ins 2, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA12 | c.280C>A p.R94S | Missense Mutation (SNP) | VAF 22/114 reads (19%) | SIFT tolerated (0.96); PolyPhen possibly damaging (0.629); catalogued as rs567588953, COSV55960138, COSV99789346; called by muse, mutect2, varscan2
- ABCA6 | c.4579A>T p.I1527F | Missense Mutation (SNP) | VAF 38/207 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV99446214; called by muse, mutect2, varscan2
- ABCE1 | c.460A>C p.N154H | Missense Mutation (SNP) | VAF 8/53 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.114); catalogued as COSV99668503; called by muse, mutect2, varscan2
- ACTC1 | c.130-1G>C p.X44_splice | Splice Site (SNP) | VAF 5/22 reads (23%) | catalogued as COSV99291754; called by muse, mutect2, varscan2
- ADGRB3 | c.3486G>C p.L1162F | Missense Mutation (SNP) | VAF 20/91 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.289); catalogued as COSV53234959, COSV99484492; called by muse, mutect2, varscan2
- ADGRL1 | c.2959C>T p.R987C (on ENST00000340736 / NM_001008701.3; = p.R982C on NM_014921.5) | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1329892867, COSV100529345; called by mutect2, varscan2
- AFF3 | c.2680G>A p.E894K | Missense Mutation (SNP) | VAF 10/70 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0.3); catalogued as rs781704362, COSV57839916; called by mutect2, varscan2
- AKAP9 | c.2155C>G p.L719V | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.33); catalogued as COSV100662221; called by muse, mutect2
- ALG13 | c.1750A>G p.K584E | Missense Mutation (SNP) | VAF 15/66 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99321944; called by muse, mutect2, varscan2
- ALPI | c.715G>A p.D239N | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT tolerated (0.17); PolyPhen benign (0.02); catalogued as COSV99785810; called by muse, mutect2, varscan2
- ANAPC2 | c.1828G>A p.E610K | Missense Mutation (SNP) | VAF 6/64 reads (9%) | SIFT tolerated (0.18); PolyPhen benign (0.027); catalogued as COSV100118982; called by muse, mutect2, varscan2
- ANKFN1 | c.1468G>T p.D490Y | Missense Mutation (SNP) | VAF 15/109 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); catalogued as COSV100593329; called by muse, mutect2, varscan2
- ANXA13 | c.616C>T p.R206* | Nonsense Mutation (SNP) | VAF 48/252 reads (19%) | catalogued as rs766941266, COSV51627094; called by muse, mutect2, varscan2
- AOC2 | c.28C>A p.L10M | Missense Mutation (SNP) | VAF 42/281 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV99513579; called by muse, mutect2, varscan2
- APOBEC3B | c.454G>T p.E152* | Nonsense Mutation (SNP) | VAF 4/34 reads (12%) | catalogued as COSV100213718; called by mutect2, varscan2
- AR | c.1984G>T p.V662L | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT tolerated (0.34); PolyPhen benign (0.034); catalogued as COSV65964072, COSV65965216; called by muse, mutect2, varscan2
- ARFGEF1 | c.4990G>A p.D1664N | Missense Mutation (SNP) | VAF 7/106 reads (7%) | SIFT tolerated (0.07); PolyPhen benign (0.066); catalogued as COSV99141796; called by muse, mutect2
- ARGFX | c.466C>A p.P156T | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.55); catalogued as COSV100544101; called by muse, mutect2, varscan2
- ASB4 | c.344G>A p.C115Y | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99987132; called by muse, mutect2, varscan2
- ASCC2 | c.1340C>A p.S447* | Nonsense Mutation (SNP) | VAF 43/245 reads (18%) | catalogued as COSV100316172, COSV100316331; called by muse, mutect2, varscan2
- ASPHD2 | c.461G>T p.R154L | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.993); catalogued as rs1250165420, COSV99313254; called by muse, mutect2, varscan2
- ASTN1 | c.1972G>C p.G658R | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99921071; called by muse, mutect2, varscan2
- ATL1 | c.987C>G p.F329L | Missense Mutation (SNP) | VAF 11/78 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.576); catalogued as COSV100612994; called by muse, mutect2, varscan2
- ATMIN | c.664G>T p.D222Y | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT tolerated (0.4); PolyPhen benign (0.051); catalogued as COSV100214572; called by mutect2, varscan2
- ATP10A | c.3789G>T p.W1263C | Missense Mutation (SNP) | VAF 10/71 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV100791064, COSV63520914; called by muse, mutect2, varscan2
- ATP1B1 | c.97+1G>T p.X33_splice | Splice Site (SNP) | VAF 6/18 reads (33%) | catalogued as rs879113954, COSV100891619; called by muse, mutect2, varscan2
- ATP2C1 | c.2185C>G p.L729V | Missense Mutation (SNP) | VAF 16/87 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs371236506; called by muse, mutect2, varscan2
- BAHCC1 | c.2935G>T p.G979C | Missense Mutation (SNP) | VAF 3/22 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV57029077; called by muse, mutect2
- C10orf90 | c.1754C>A p.S585Y | Missense Mutation (SNP) | VAF 17/101 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52958706; called by muse, mutect2, varscan2
- C5 | c.4240G>T p.E1414* | Nonsense Mutation (SNP) | VAF 14/102 reads (14%) | catalogued as COSV56326132, COSV99797588; called by muse, mutect2, varscan2
- C6 | c.1705G>T p.G569C | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.963); catalogued as rs754488543, COSV99666867; called by muse, mutect2, varscan2
- C8orf37 | c.82G>A p.E28K | Missense Mutation (SNP) | VAF 29/248 reads (12%) | SIFT tolerated (0.11); PolyPhen benign (0.015); catalogued as rs768222931, COSV99713106; called by muse, mutect2, varscan2
- CA10 | c.893G>T p.R298L | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99562395; called by mutect2, varscan2
- CCDC127 | c.227C>G p.A76G | Missense Mutation (SNP) | VAF 8/74 reads (11%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as COSV99722937; called by muse, mutect2, varscan2
- CCDC92 | c.131C>A p.T44K | Missense Mutation (SNP) | VAF 13/96 reads (14%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV99435417; called by muse, varscan2
- CCDC92 | c.130A>C p.T44P | Missense Mutation (SNP) | VAF 13/97 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV99435420; called by muse, varscan2
- CDH18 | c.355G>T p.E119* | Nonsense Mutation (SNP) | VAF 31/108 reads (29%) | catalogued as COSV99933587; called by muse, mutect2, varscan2
- CDH9 | c.746C>G p.S249C | Missense Mutation (SNP) | VAF 11/103 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV50375363, COSV99142888; called by muse, mutect2, varscan2
- CDYL | c.808C>G p.P270A (on ENST00000328908 / NM_001368125.1; = p.P216A on NM_004824.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.184); catalogued as COSV100189098; called by muse, mutect2, varscan2
- CFAP69 | c.913G>T p.D305Y | Missense Mutation (SNP) | VAF 8/75 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV100289982; called by muse, mutect2, varscan2
- CFTR | c.388C>T p.L130F | Missense Mutation (SNP) | VAF 24/123 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV50075296, COSV99135131, COSV99135516; called by muse, mutect2, varscan2
- CHRD | c.889G>C p.V297L | Missense Mutation (SNP) | VAF 12/93 reads (13%) | SIFT tolerated (0.6); PolyPhen benign (0.033); catalogued as COSV99200330; called by muse, mutect2, varscan2
- CHRDL2 | c.706G>T p.G236C | Missense Mutation (SNP) | VAF 8/57 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as rs1193510812, COSV99733677; called by muse, mutect2, varscan2
- CLEC4F | c.562G>C p.E188Q | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.941); catalogued as COSV99713672, COSV99713850; called by muse, mutect2, varscan2
- COL13A1 | c.1643G>T p.G548V (on ENST00000398978 / NM_001130103.2; = p.G491V on NM_080798.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100637401; called by muse, mutect2, varscan2
- COL26A1 | c.173A>T p.H58L | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.239); catalogued as COSV100561631; called by muse, mutect2, varscan2
- CR1L | c.1583C>A p.P528H | Missense Mutation (SNP) | VAF 24/133 reads (18%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.873); catalogued as COSV99687069; called by muse, mutect2, varscan2
- CSMD3 | c.10331T>C p.L3444S (on ENST00000297405 / NM_001363185.1; = p.L3275S on NM_052900.3) | Missense Mutation (SNP) | VAF 11/79 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99830633; called by muse, mutect2, varscan2
- CSMD3 | c.2015A>T p.Y672F (on ENST00000297405 / NM_001363185.1; = p.Y568F on NM_052900.3) | Missense Mutation (SNP) | VAF 14/168 reads (8%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.858); catalogued as COSV99830637; called by muse, mutect2
- DGKI | c.1207C>A p.P403T | Missense Mutation (SNP) | VAF 41/115 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99933422; called by muse, mutect2, varscan2
- DMBT1 | c.2411G>T p.G804V | Missense Mutation (SNP) | VAF 23/72 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs963526763, COSV100352650, COSV100352669; called by muse, mutect2, varscan2
- DMWD | c.1715G>T p.R572L | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.085); catalogued as rs765984271, COSV99352979; called by mutect2, varscan2
- DNAH11 | c.10825G>A p.E3609K | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT tolerated (0.11); PolyPhen benign (0.007); catalogued as COSV100178505; called by muse, mutect2, varscan2
- DNAH5 | c.2177A>G p.Q726R | Missense Mutation (SNP) | VAF 11/111 reads (10%) | SIFT tolerated (0.54); PolyPhen benign (0.001); catalogued as COSV99447903; called by muse, mutect2, varscan2
- DPF3 | c.544G>T p.G182C | Missense Mutation (SNP) | VAF 12/79 reads (15%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.575); catalogued as COSV100818487; called by muse, mutect2, varscan2
- DTNA | c.475A>G p.S159G | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT tolerated (0.11); PolyPhen benign (0.114); catalogued as COSV99311987; called by mutect2, varscan2
- ERCC6L | c.2349G>T p.E783D | Missense Mutation (SNP) | VAF 52/124 reads (42%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as COSV100559068; called by muse, mutect2, varscan2
- FLG | c.5480C>A p.S1827Y | Missense Mutation (SNP) | VAF 24/433 reads (6%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.974); catalogued as rs1361375721, COSV100911399; called by muse, mutect2
- FRMPD4 | c.2245G>A p.E749K | Missense Mutation (SNP) | VAF 19/95 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.955); catalogued as COSV101042593, COSV66217632; called by muse, mutect2, varscan2
- GALNTL5 | c.706T>C p.W236R | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs755106841, COSV101217753; called by muse, mutect2, varscan2
- GRIA4 | c.728G>T p.G243V | Missense Mutation (SNP) | VAF 6/49 reads (12%) | SIFT tolerated (0.56); PolyPhen probably damaging (1); catalogued as COSV56911735; called by muse, mutect2, varscan2
- GRIP1 | c.2945T>G p.V982G (on ENST00000359742 / NM_001379345.1; = p.V930G on NM_021150.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 28/191 reads (15%) | SIFT tolerated (0.34); PolyPhen benign (0.04); catalogued as COSV99668947; called by muse, mutect2, varscan2
- GRIP1 | c.1724A>T p.K575M (on ENST00000359742 / NM_001379345.1; = p.K523M on NM_021150.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as COSV99668951; called by mutect2, varscan2
- GSTA3 | c.590T>C p.F197S | Missense Mutation (SNP) | VAF 14/98 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99274490; called by muse, mutect2, varscan2
- HCN1 | c.2285C>A p.T762K | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT tolerated, low confidence (0.57); PolyPhen benign (0.081); catalogued as COSV100299634, COSV57491554; called by muse, mutect2, varscan2
- HDLBP | c.2416C>G p.L806V | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT tolerated (0.29); PolyPhen benign (0.001); catalogued as COSV100190284; called by muse, mutect2, varscan2
- HDLBP | c.2184C>A p.F728L | Missense Mutation (SNP) | VAF 13/68 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.182); catalogued as COSV100190289; called by muse, varscan2
- HEY2 | c.671C>G p.S224C | Missense Mutation (SNP) | VAF 14/180 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.707); catalogued as COSV100856350, COSV64240483; called by muse, mutect2
- HFM1 | c.511G>T p.D171Y | Missense Mutation (SNP) | VAF 11/80 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.781); catalogued as COSV99645799; called by muse, mutect2, varscan2
- HIVEP2 | c.6272G>A p.R2091K | Missense Mutation (SNP) | VAF 8/73 reads (11%) | SIFT tolerated (0.46); PolyPhen probably damaging (0.952); catalogued as COSV99172372; called by muse, mutect2, varscan2
- HS3ST3A1 | c.1142G>C p.R381P | Missense Mutation (SNP) | VAF 6/74 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.317); catalogued as COSV52375380; called by muse, varscan2
- HS6ST3 | c.1132C>A p.Q378K | Missense Mutation (SNP) | VAF 9/60 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); catalogued as COSV100940321, COSV65002569; called by muse, mutect2, varscan2
- IDI2 | c.22T>A p.W8R | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as COSV99479169; called by muse, mutect2, varscan2
- IFT122 | c.1114G>T p.V372F (on ENST00000348417 / NM_052989.3; = p.V313F on NM_018262.4) | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99959077; called by mutect2, varscan2
- IGSF9 | c.1862C>T p.P621L (on ENST00000368094 / NM_001135050.2; = p.P605L on NM_020789.4) | Missense Mutation (SNP) | VAF 22/63 reads (35%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as rs546681175, COSV63639444; called by muse, mutect2, varscan2
- IL13RA1 | c.784G>A p.V262I | Missense Mutation (SNP) | VAF 24/119 reads (20%) | SIFT tolerated (0.19); PolyPhen benign (0.015); catalogued as COSV100861707; called by muse, mutect2, varscan2
- IMPA1 | c.490G>T p.G164C | Missense Mutation (SNP) | VAF 19/63 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1313019644, COSV56273587, COSV99808887; called by muse, mutect2, varscan2
- INSR | c.3722C>G p.S1241C | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as COSV57168748; called by muse, mutect2, varscan2
- IQCJ-SCHIP1 | c.1106G>A p.R369Q (on ENST00000485419 / NM_001197113.1; = p.R293Q on NM_014575.3) | Missense Mutation (SNP) | VAF 20/128 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs767522191, COSV61838173; called by muse, mutect2, varscan2
- KCNH8 | c.2665A>G p.R889G | Missense Mutation (SNP) | VAF 6/53 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.097); catalogued as rs1360880137, COSV100111275; called by muse, mutect2, varscan2
- KEAP1 | c.919G>A p.E307K | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.027); catalogued as COSV50260706, COSV99407609; called by muse, mutect2, varscan2
- KHSRP | c.1364G>A p.G455E | Missense Mutation (SNP) | VAF 10/63 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101231171; called by muse, mutect2, varscan2
- KIAA0319 | c.1469G>T p.R490L | Missense Mutation (SNP) | VAF 8/74 reads (11%) | SIFT tolerated (0.46); PolyPhen benign (0.165); catalogued as COSV65500783; called by mutect2, varscan2
- KIF21B | c.679G>A p.A227T | Missense Mutation (SNP) | VAF 14/67 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1200416395, COSV59758331; called by muse, mutect2, varscan2
- KIF26A | c.2015A>G p.K672R | Missense Mutation (SNP) | VAF 11/53 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs1489038183, COSV100181014; called by muse, mutect2
- KL | c.1599A>T p.Q533H | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.316); catalogued as COSV101199068; called by muse, mutect2, varscan2
- KLHL23 | c.1609T>C p.W537R | Missense Mutation (SNP) | VAF 12/140 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99775663; called by muse, mutect2
- KRT33B | c.145G>C p.E49Q | Missense Mutation (SNP) | VAF 10/122 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.975); catalogued as rs553797257, COSV99290550; called by muse, mutect2
- LAMA2 | c.1252C>T p.P418S | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0.068); catalogued as COSV101370330; called by muse, mutect2, varscan2
- LDAH | c.862G>T p.E288* | Nonsense Mutation (SNP) | VAF 14/53 reads (26%) | catalogued as COSV99425505; called by muse, mutect2, varscan2
- LRCH4 | c.950C>T p.S317L | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT tolerated (0.18); PolyPhen benign (0.013); catalogued as COSV100052842; called by muse, mutect2, varscan2
- LRP1B | c.6119C>A p.A2040E | Missense Mutation (SNP) | VAF 20/103 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.159); catalogued as COSV101255037; called by muse, mutect2, varscan2
- LRRC40 | c.842A>G p.E281G | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as rs757402855, COSV100918736; called by muse, mutect2, varscan2
- LRRC66 | c.2591C>G p.S864* | Nonsense Mutation (SNP) | VAF 6/88 reads (7%) | catalogued as COSV100602910; called by muse, mutect2
- LRRC7 | c.964G>C p.D322H (on ENST00000651989 / NM_001370785.2; = p.D289H on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 21/154 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV50496995, COSV50601277; called by muse, mutect2, varscan2
- LRRTM3 | c.1666A>T p.T556S | Missense Mutation (SNP) | VAF 15/64 reads (23%) | SIFT tolerated, low confidence (0.95); PolyPhen benign (0.003); catalogued as COSV100791577; called by muse, mutect2, varscan2
- MAP3K15 | c.1437C>A p.V479= | Splice Region (SNP) | VAF 4/14 reads (29%) | catalogued as COSV100134510; called by muse, mutect2
- MAPKAP1 | c.451C>G p.L151V | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT tolerated (0.33); PolyPhen benign (0.047); catalogued as COSV99784655; called by muse, mutect2, varscan2
- MAST1 | c.569C>A p.T190N | Missense Mutation (SNP) | VAF 3/10 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99262674; called by muse, mutect2
- MCF2 | c.1365G>C p.G455= | Splice Region (SNP) | VAF 19/70 reads (27%) | catalogued as COSV100644665; called by muse, mutect2, varscan2
- MEF2B | c.676-1G>C p.X226_splice | Splice Site (SNP) | VAF 5/22 reads (23%) | catalogued as COSV99364535; called by muse, mutect2, varscan2
- MEN1 | c.1001G>T p.C334F | Missense Mutation (SNP) | VAF 12/150 reads (8%) | SIFT tolerated (0.53); PolyPhen benign (0.015); catalogued as COSV99580691; called by muse, mutect2
- MGAT2 | c.230C>T p.P77L | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT tolerated (0.32); PolyPhen benign (0.005); catalogued as rs372538664; called by muse, mutect2
- MGME1 | c.100T>A p.S34T | Missense Mutation (SNP) | VAF 13/83 reads (16%) | SIFT tolerated (0.38); PolyPhen benign (0.023); catalogued as COSV100891345; called by muse, mutect2, varscan2
- MMAA | c.885G>T p.L295F | Missense Mutation (SNP) | VAF 29/116 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV99849744; called by muse, mutect2, varscan2
- MMP20 | c.625G>C p.E209Q | Missense Mutation (SNP) | VAF 19/103 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs199788797, COSV99497577; called by muse, mutect2, varscan2
- MMRN2 | c.514G>T p.V172L | Missense Mutation (SNP) | VAF 8/68 reads (12%) | SIFT tolerated (0.37); PolyPhen benign (0.003); catalogued as COSV100922546; called by mutect2, varscan2
- MUC16 | c.21458C>T p.P7153L | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.047); catalogued as rs1289597761, COSV101199316; called by muse, mutect2, varscan2
- MUC7 | c.509C>A p.P170H | Missense Mutation (SNP) | VAF 22/130 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.823); catalogued as COSV100512246; called by muse, varscan2
- MYH1 | c.1146A>T p.E382D | Missense Mutation (SNP) | VAF 28/175 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.028); catalogued as COSV99875481; called by muse, mutect2, varscan2
- MYH2 | c.4166C>G p.T1389R | Missense Mutation (SNP) | VAF 23/128 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.968); catalogued as COSV99819800; called by muse, mutect2, varscan2
- NCOR2 | c.2260C>A p.P754T | Missense Mutation (SNP) | VAF 13/86 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1333540307, COSV100657137; called by muse, mutect2, varscan2
- NDST3 | c.1253A>G p.Y418C | Missense Mutation (SNP) | VAF 8/74 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99630129; called by mutect2, varscan2
- NELL2 | c.236A>G p.Q79R | Missense Mutation (SNP) | VAF 24/136 reads (18%) | SIFT tolerated (0.05); PolyPhen benign (0.001); catalogued as rs1379064978, COSV100419265; called by muse, mutect2, varscan2
- NLRP5 | c.2201G>T p.R734L | Missense Mutation (SNP) | VAF 26/121 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.621); catalogued as COSV101173528, COSV66762506, COSV66765656; called by muse, mutect2, varscan2
- NPAP1 | c.546C>A p.S182R | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT tolerated (0.55); PolyPhen possibly damaging (0.668); catalogued as rs761309766, COSV61504000, COSV61505225; called by muse, mutect2, varscan2
- NPR2 | c.1887G>C p.K629N | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV100709425; called by muse, mutect2, varscan2
- NSUN3 | c.129A>G p.I43M | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.201); catalogued as COSV100113199; called by muse, mutect2, varscan2
- NWD1 | c.2242G>C p.E748Q | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.203); catalogued as COSV100342297, COSV60340766; called by muse, mutect2, varscan2
- NYAP2 | c.1496C>A p.P499Q | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT tolerated (0.67); PolyPhen benign (0.007); catalogued as COSV56005652, COSV56016052, COSV99796255; called by mutect2, varscan2
- OBSCN | c.20366C>T p.S6789F | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.831); catalogued as rs755643834, COSV100802984; called by mutect2, varscan2
- OLFM3 | c.1173G>C p.K391N (on ENST00000338858 / NM_001288821.1; = p.K371N on NM_058170.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100129195; called by muse, mutect2
- OR10AG1 | c.106A>T p.I36L | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0.144); catalogued as rs1328227884, COSV56632248; called by muse, mutect2, varscan2
- OR10T2 | c.173C>T p.T58I | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT tolerated (0.09); PolyPhen benign (0.021); catalogued as COSV100554912; called by muse, mutect2, varscan2
- OR12D2 | c.-1G>A | Splice Region (SNP) | VAF 43/247 reads (17%) | catalogued as COSV101011196; called by muse, mutect2, varscan2
- OR14I1 | c.447C>A p.S149R | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as COSV100700461; called by muse, mutect2, varscan2
- OR2T1 | c.908C>A p.A303D | Missense Mutation (SNP) | VAF 18/95 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0.14); catalogued as rs1244611327, COSV100822285; called by muse, mutect2, varscan2
- OR4C46 | c.343G>A p.V115M | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.18); catalogued as COSV100060581; called by muse, mutect2, varscan2
- OR4D2 | c.607A>T p.S203C | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101613849; called by muse, mutect2, varscan2
- OR51M1 | c.742C>T p.R248C | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.921); catalogued as rs1204694306, COSV60784013, COSV60784470; called by mutect2, varscan2
- OR52E6 | c.318C>G p.I106M | Missense Mutation (SNP) | VAF 19/126 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.213); catalogued as COSV100259257; called by muse, mutect2, varscan2
- OR5H15 | c.415G>A p.G139R | Missense Mutation (SNP) | VAF 29/170 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV100736645; called by muse, mutect2, varscan2
- OR6F1 | c.216G>A p.W72* | Nonsense Mutation (SNP) | VAF 13/46 reads (28%) | catalogued as COSV100129084; called by muse, mutect2, varscan2
- P3H3 | c.1541C>G p.T514R | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as COSV99301088; called by muse, mutect2, varscan2
- PANX1 | c.881C>T p.T294M | Missense Mutation (SNP) | VAF 15/83 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.475); catalogued as rs577336224, COSV99921744; called by muse, mutect2, varscan2
- PATZ1 | c.289G>A p.G97R | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.421); catalogued as rs1460875506, COSV99315261; called by muse, mutect2, varscan2
- PCDHA4 | c.649G>A p.G217R | Missense Mutation (SNP) | VAF 25/83 reads (30%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.887); catalogued as COSV100793299; called by muse, mutect2, varscan2
- PCDHA5 | c.1214C>G p.S405W | Missense Mutation (SNP) | VAF 33/167 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV100972210; called by muse, mutect2, varscan2
- PCDHA7 | c.983C>T p.P328L | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.039); catalogued as COSV100971366; called by muse, mutect2, varscan2
- PCDHB3 | c.1329C>A p.D443E | Missense Mutation (SNP) | VAF 25/88 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV50574236, COSV99166875; called by muse, mutect2, varscan2
- PCF11 | c.2708G>C p.R903T | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.328); catalogued as COSV100018103; called by muse, mutect2, varscan2
- PDE1C | c.233G>T p.R78L | Missense Mutation (SNP) | VAF 9/65 reads (14%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.717); catalogued as COSV101275457, COSV68819282; called by mutect2, varscan2
- PEG3 | c.3709A>T p.S1237C | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.956); catalogued as COSV99688318; called by mutect2, varscan2
- PEG3 | c.1984T>A p.C662S | Missense Mutation (SNP) | VAF 16/183 reads (9%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.813); catalogued as COSV55645754, COSV99688320; called by muse, mutect2
- PHC3 | c.1819G>C p.D607H (on ENST00000494943 / NM_001308116.2; = p.D619H on NM_024947.4) | Missense Mutation (SNP) | VAF 7/60 reads (12%) | SIFT tolerated (0.11); PolyPhen benign (0.28); catalogued as COSV101520150; called by muse, mutect2, varscan2
- PIK3CB | c.2635G>C p.D879H | Missense Mutation (SNP) | VAF 8/80 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as COSV100005442; called by muse, mutect2
- PKHD1 | c.9591G>C p.Q3197H | Missense Mutation (SNP) | VAF 17/78 reads (22%) | SIFT tolerated (0.52); PolyPhen benign (0.017); catalogued as rs1421251307, COSV100582391; called by muse, mutect2, varscan2
- PLSCR1 | c.296T>C p.L99S | Missense Mutation (SNP) | VAF 14/98 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100678344; called by muse, mutect2, varscan2
- PLXNA2 | c.3505C>A p.L1169I | Missense Mutation (SNP) | VAF 12/104 reads (12%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.872); catalogued as COSV100885311; called by muse, mutect2, varscan2
- PNLIPRP3 | c.1194G>A p.M398I | Missense Mutation (SNP) | VAF 21/94 reads (22%) | SIFT tolerated (0.16); PolyPhen benign (0.009); catalogued as COSV100982442; called by muse, mutect2, varscan2
- PPAN-P2RY11 | c.1642T>C p.Y548H | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs1363112595, COSV99461127; called by mutect2, varscan2
- PPAT | c.376G>A p.V126I | Missense Mutation (SNP) | VAF 18/141 reads (13%) | SIFT tolerated (0.17); PolyPhen benign (0.077); catalogued as rs756567329, COSV99947170; called by muse, mutect2, varscan2
- PPP1CA | c.923A>T p.Q308L | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.001); catalogued as COSV100334923; called by mutect2, varscan2
- PPP2CA | c.619G>T p.G207C | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as COSV99196033; called by muse, mutect2, varscan2
- PRKACB | c.656C>T p.A219V | Missense Mutation (SNP) | VAF 18/142 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs1309386302, COSV100853909; called by muse, mutect2, varscan2
- PROX1 | c.982G>A p.E328K | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT tolerated (0.25); PolyPhen benign (0.089); catalogued as COSV99799057; called by muse, mutect2, varscan2
- PRRC2A | c.1402C>T p.R468W | Missense Mutation (SNP) | VAF 18/93 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100784550; called by muse, mutect2, varscan2
- PRSS16 | c.215C>G p.S72C | Missense Mutation (SNP) | VAF 4/37 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); catalogued as COSV100041892; called by mutect2, varscan2
- PSG3 | c.180G>C p.Q60H | Missense Mutation (SNP) | VAF 35/208 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as COSV100548840; called by muse, mutect2, varscan2
- PTF1A | c.168G>T p.Q56H | Missense Mutation (SNP) | VAF 3/17 reads (18%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.005); catalogued as COSV100919578; called by muse, mutect2
- PTPRO | c.2770G>C p.D924H (on ENST00000281171 / NM_030667.3; = p.D896H on NM_002848.4) | Missense Mutation (SNP) | VAF 15/112 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.719); catalogued as COSV99840231; called by muse, mutect2, varscan2
- RAD17 | c.490C>A p.P164T (on ENST00000380774 / NM_133339.2; = p.P153T on NM_002873.1) | Missense Mutation (SNP) | VAF 6/59 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99281342; called by muse, mutect2
- RBMS2 | c.361G>C p.G121R | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.577); catalogued as COSV100008457, COSV56266017; called by mutect2, varscan2
- REL | c.1510G>A p.D504N | Missense Mutation (SNP) | VAF 17/82 reads (21%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0.395); catalogued as COSV99691990; called by muse, mutect2, varscan2
- RGS22 | c.2474G>T p.G825V | Missense Mutation (SNP) | VAF 18/71 reads (25%) | SIFT tolerated (0.07); PolyPhen benign (0.01); catalogued as rs1221418331, COSV100693141, COSV100693878; called by muse, mutect2, varscan2
- ROBO1 | c.3322G>T p.E1108* | Nonsense Mutation (SNP) | VAF 12/63 reads (19%) | catalogued as COSV71399989; called by muse, mutect2, varscan2
- RUBCN | c.1762G>A p.E588K | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.427); catalogued as rs550326951, COSV99583729; called by muse, mutect2
- RUSC1 | c.2248C>G p.L750V (on ENST00000368352 / NM_001105203.2; = p.L281V on NM_014328.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.753); catalogued as COSV99429659; called by muse, mutect2, varscan2
- RYR1 | c.4331C>A p.P1444H | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100615353; called by muse, mutect2, varscan2
- SAFB2 | c.2296C>A p.H766N | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT tolerated (0.14); PolyPhen benign (0.025); catalogued as COSV99385586; called by muse, mutect2, varscan2
- SCGB2A1 | c.171G>T p.E57D | Missense Mutation (SNP) | VAF 14/117 reads (12%) | SIFT tolerated (0.49); PolyPhen benign (0.026); catalogued as COSV99793720; called by muse, mutect2, varscan2
- SEPTIN10 | c.451G>A p.E151K | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV61779959; called by muse, mutect2, varscan2
- SERPINI2 | c.247+1G>A p.X83_splice | Splice Site (SNP) | VAF 16/128 reads (13%) | catalogued as COSV99247802; called by muse, mutect2, varscan2
- SLC14A2 | c.890A>G p.D297G | Missense Mutation (SNP) | VAF 8/102 reads (8%) | SIFT tolerated (0.17); PolyPhen benign (0.019); catalogued as COSV99675328; called by muse, mutect2
- SLC27A3 | c.351G>C p.W117C | Missense Mutation (SNP) | VAF 13/117 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.321); catalogued as COSV99669873; called by muse, mutect2, varscan2
- SLC2A3 | c.1267G>T p.A423S | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.964); catalogued as rs201737691, COSV50002302, COSV50003055; called by muse, mutect2, varscan2
- SLC35G1 | c.456G>C p.Q152H (on ENST00000427197 / NM_001134658.3; = p.Q151H on NM_153226.4) | Missense Mutation (SNP) | VAF 20/117 reads (17%) | SIFT tolerated (0.16); PolyPhen benign (0.16); catalogued as COSV101004045; called by muse, mutect2, varscan2
- SLC38A6 | c.115A>T p.R39* | Nonsense Mutation (SNP) | VAF 21/90 reads (23%) | catalogued as COSV99712050; called by muse, mutect2, varscan2
- SLC46A3 | c.1354G>C p.E452Q | Missense Mutation (SNP) | VAF 24/126 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.276); catalogued as COSV99906211; called by muse, mutect2, varscan2
- SLC4A9 | c.1920C>A p.F640L (on ENST00000507527 / NM_001258428.2; = p.F616L on NM_031467.3) | Missense Mutation (SNP) | VAF 26/166 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV99138636; called by muse, mutect2, varscan2
- SLC6A16 | c.764C>T p.S255L | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs1368765660, COSV100242664; called by muse, mutect2, varscan2
- SLC7A3 | c.841C>A p.Q281K | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.05); catalogued as COSV53228660; called by muse, mutect2, varscan2
- SLC9A8 | c.365G>A p.R122H | Missense Mutation (SNP) | VAF 6/64 reads (9%) | SIFT tolerated (0.2); PolyPhen benign (0.023); catalogued as rs749505248, COSV64291510; called by mutect2, varscan2
- SLC9B2 | c.925G>A p.E309K | Missense Mutation (SNP) | VAF 16/116 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV100293969; called by muse, mutect2, varscan2
- SMARCB1 | c.96G>A p.V32= | Splice Region (SNP) | VAF 31/212 reads (15%) | catalogued as COSV99575134; called by muse, mutect2, varscan2
- SMG5 | c.1243A>T p.S415C | Missense Mutation (SNP) | VAF 17/69 reads (25%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.866); catalogued as COSV100700758; called by muse, mutect2, varscan2
- SORCS1 | c.1030C>T p.H344Y | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT tolerated (0.46); PolyPhen benign (0.071); catalogued as COSV99545071; called by muse, mutect2, varscan2
- STARD6 | c.415C>T p.P139S | Missense Mutation (SNP) | VAF 16/139 reads (12%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); catalogued as rs1257511221, COSV100323399; called by muse, mutect2, varscan2
- STEAP1 | c.76G>A p.D26N | Missense Mutation (SNP) | VAF 14/69 reads (20%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0.003); catalogued as rs758880644, COSV99787596; called by muse, mutect2, varscan2
- STON1 | c.2185A>G p.I729V | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as rs1370891963, COSV100561698; called by muse, mutect2, varscan2
- SYNE1 | c.21814A>G p.K7272E (on ENST00000367255 / NM_182961.4; = p.K7201E on NM_033071.3) | Missense Mutation (SNP) | VAF 14/154 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.888); catalogued as COSV99559310; called by muse, mutect2
- SYNE1 | c.10700C>G p.A3567G (on ENST00000367255 / NM_182961.4; = p.A3574G on NM_033071.3) | Missense Mutation (SNP) | VAF 10/114 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.021); catalogued as COSV99559317; called by muse, mutect2
- SYNE2 | c.460G>T p.D154Y | Missense Mutation (SNP) | VAF 36/188 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as COSV100420118; called by muse, mutect2, varscan2
- SYNE2 | c.959C>T p.S320L | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT tolerated (0.05); PolyPhen benign (0.36); catalogued as COSV100420120; called by muse, mutect2, varscan2
- TANC1 | c.2396C>A p.S799Y | Missense Mutation (SNP) | VAF 23/82 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV99713538, COSV99715071; called by muse, mutect2, varscan2
- TBX19 | c.383C>A p.S128Y | Missense Mutation (SNP) | VAF 21/120 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM014745, COSV100892342; called by muse, mutect2, varscan2
- TDRD5 | c.764T>A p.M255K | Missense Mutation (SNP) | VAF 18/112 reads (16%) | SIFT tolerated (0.53); PolyPhen benign (0.001); catalogued as COSV99675919; called by muse, mutect2, varscan2
- TFEB | c.699G>T p.E233D | Missense Mutation (SNP) | VAF 17/72 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as rs745674792, COSV100026106; called by muse, mutect2, varscan2
- TLE6 | c.1468A>G p.S490G (on ENST00000246112 / NM_001143986.2; = p.S367G on NM_024760.3) | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.795); catalogued as rs1317512322, COSV99504186; called by muse, mutect2, varscan2
- TM4SF1 | c.260G>A p.R87Q | Missense Mutation (SNP) | VAF 30/210 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.335); catalogued as rs746963430, COSV59525444, COSV59525888; called by muse, mutect2, varscan2
- TMEM89 | c.440G>A p.R147Q | Missense Mutation (SNP) | VAF 17/102 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs140040188; called by muse, mutect2, varscan2
- TMPRSS11A | c.334G>C p.E112Q | Missense Mutation (SNP) | VAF 9/145 reads (6%) | SIFT tolerated (0.13); PolyPhen benign (0.038); catalogued as COSV100602621; called by muse, mutect2
- TMX3 | c.1153C>T p.P385S | Missense Mutation (SNP) | VAF 12/80 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV100218303; called by muse, mutect2, varscan2
- TNKS | c.2492G>A p.R831K | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.941); catalogued as COSV100126633; called by muse, mutect2, varscan2
- TP53 | c.132del p.M44Ifs*79 | Frame Shift Del (DEL) | VAF 55/198 reads (28%) | catalogued as COSV53759087; called by mutect2, pindel, varscan2
- TP53BP2 | c.1382G>T p.R461L (on ENST00000343537 / NM_001031685.3; = p.R332L on NM_005426.2) | Missense Mutation (SNP) | VAF 9/73 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.386); catalogued as COSV100636563, COSV59066991; called by mutect2, varscan2
- TRA2B | c.245G>A p.R82H | Missense Mutation (SNP) | VAF 17/91 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as rs764180360, COSV99373232; called by muse, mutect2, varscan2
- TRIM42 | c.981C>G p.I327M | Missense Mutation (SNP) | VAF 10/82 reads (12%) | SIFT tolerated (0.13); PolyPhen benign (0.141); catalogued as COSV99648222, COSV99648902; called by muse, mutect2, varscan2
- TTN | c.79781C>A p.A26594D (on ENST00000591111; = p.A19170D on NM_003319.4) | Missense Mutation (SNP) | VAF 18/139 reads (13%) | PolyPhen probably damaging (0.925); catalogued as rs1176082000, COSV100604309; called by muse, mutect2, varscan2
- TTN | c.41975G>T p.G13992V (on ENST00000591111; = p.G6568V on NM_003319.4) | Missense Mutation (SNP) | VAF 15/93 reads (16%) | PolyPhen probably damaging (1); catalogued as COSV100604312, COSV60224458; called by muse, mutect2, varscan2
- TTN | c.31704G>T p.M10568I (on ENST00000591111; = p.M9641I on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/23 reads (26%) | PolyPhen benign (0.003); catalogued as COSV60372820; called by muse, mutect2, varscan2
- TWNK | c.913G>A p.V305I | Missense Mutation (SNP) | VAF 18/93 reads (19%) | SIFT tolerated (0.62); PolyPhen benign (0.001); catalogued as rs753457416, COSV99272240; called by muse, mutect2, varscan2
- UBE3A | c.820C>G p.H274D | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT tolerated (0.22); PolyPhen benign (0.033); catalogued as COSV99217016; called by muse, mutect2, varscan2
- UNC13C | c.2750C>A p.P917Q | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT tolerated, low confidence (0.21); PolyPhen possibly damaging (0.548); catalogued as COSV99514843; called by muse, mutect2, varscan2
- USH2A | c.13380A>G p.I4460M | Missense Mutation (SNP) | VAF 18/82 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as rs1244395010, COSV100232571; called by muse, mutect2, varscan2
- VAV1 | c.266A>T p.K89M | Missense Mutation (SNP) | VAF 20/100 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV100408879; called by muse, mutect2, varscan2
- VPS13C | c.10444A>G p.T3482A (on ENST00000644861 / NM_020821.3; = p.T3439A on NM_017684.5) | Missense Mutation (SNP) | VAF 18/132 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as rs780965164, COSV99827988; called by muse, mutect2
- WAPL | c.3531G>T p.Q1177H | Missense Mutation (SNP) | VAF 9/57 reads (16%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.894); catalogued as COSV99556401; called by muse, mutect2, varscan2
- WASHC5 | c.3194G>A p.R1065Q | Missense Mutation (SNP) | VAF 27/73 reads (37%) | SIFT tolerated (0.07); PolyPhen benign (0.089); catalogued as COSV59193995, COSV59194172; called by muse, mutect2, varscan2
- ZIC1 | c.178G>T p.G60C | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.996); catalogued as rs748870052, COSV99291768; called by mutect2, varscan2
- ZNF182 | c.1375G>C p.E459Q | Missense Mutation (SNP) | VAF 10/69 reads (14%) | SIFT tolerated (0.15); PolyPhen benign (0.062); catalogued as COSV100526993, COSV59357666; called by muse, mutect2, varscan2
- ZNF184 | c.2234A>G p.Q745R | Missense Mutation (SNP) | VAF 15/143 reads (10%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.632); catalogued as COSV99279530; called by muse, mutect2, varscan2
- ZNF197 | c.1543T>C p.C515R | Missense Mutation (SNP) | VAF 19/70 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100482037; called by muse, mutect2, varscan2
- ZNF257 | c.1033C>A p.Q345K | Missense Mutation (SNP) | VAF 13/84 reads (15%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs555293490, COSV71310222, COSV71312175, COSV71312346; called by muse, mutect2, varscan2
- ZNF296 | c.854C>T p.P285L | Missense Mutation (SNP) | VAF 18/71 reads (25%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as rs113643466; called by muse, mutect2, varscan2
- ZNF443 | c.316A>G p.S106G | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as COSV100042054; called by muse, mutect2, varscan2
- ZNF530 | c.1222G>T p.V408L | Missense Mutation (SNP) | VAF 18/84 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.025); catalogued as COSV100252480; called by muse, mutect2, varscan2
- ZNF536 | c.2584G>T p.G862W | Missense Mutation (SNP) | VAF 5/63 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV100834992; called by muse, mutect2
- ZNF681 | c.962A>T p.Q321L | Missense Mutation (SNP) | VAF 11/81 reads (14%) | SIFT tolerated (0.72); PolyPhen benign (0.122); catalogued as COSV101267432; called by muse, mutect2, varscan2
- ZNF804A | c.2126T>C p.I709T | Missense Mutation (SNP) | VAF 14/82 reads (17%) | SIFT tolerated (0.15); PolyPhen benign (0.203); catalogued as COSV100167276; called by muse, mutect2
- ZNF836 | c.1610A>G p.E537G | Missense Mutation (SNP) | VAF 13/85 reads (15%) | SIFT tolerated (0.28); PolyPhen benign (0.039); catalogued as COSV100440798; called by muse, mutect2, varscan2
- CNPY4 | c.34C>G p.L12V | Missense Mutation (SNP) | VAF 8/76 reads (11%) | SIFT tolerated (0.47); PolyPhen benign (0); called by mutect2, varscan2
- GPR179 | c.1394T>A p.I465K (on ENST00000621958; = p.I464K on NM_001004334.4) | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.84); called by muse, mutect2, varscan2
- IGHV1-45 | c.152G>T p.R51L | Missense Mutation (SNP) | VAF 20/109 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0); called by muse, mutect2, varscan2
- ILDR2 | c.277dup p.C93Lfs*35 | Frame Shift Ins (INS) | VAF 11/92 reads (12%) | called by mutect2, pindel, varscan2
- MVB12A | c.471del p.K158Sfs*85 | Frame Shift Del (DEL) | VAF 10/38 reads (26%) | called by mutect2, pindel, varscan2
- OR2F1 | c.677del p.L226Qfs*56 | Frame Shift Del (DEL) | VAF 11/79 reads (14%) | called by mutect2, pindel, varscan2
- OR56A3 | c.711dup p.V238Rfs*32 | Frame Shift Ins (INS) | VAF 18/95 reads (19%) | called by mutect2, pindel, varscan2
- RANBP3 | c.425T>A p.F142Y | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.993); called by mutect2, varscan2
- SERINC5 | c.1161_1177del p.Y388Pfs*? | Frame Shift Del (DEL) | VAF 14/98 reads (14%) | called by mutect2, pindel
- SPIDR | c.213del p.I72Lfs*28 | Frame Shift Del (DEL) | VAF 27/212 reads (13%) | called by mutect2, pindel, varscan2
- SVEP1 | c.6408del p.M2137Cfs*17 | Frame Shift Del (DEL) | VAF 5/41 reads (12%) | called by mutect2, pindel, varscan2
- TRAV30 | c.298C>G p.Q100E | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT tolerated (0.08); PolyPhen benign (0.259); called by muse, mutect2, varscan2
- A4GNT | c.933C>T p.L311= | Silent (SNP) | VAF 21/66 reads (32%) | catalogued as COSV99367780; called by muse, mutect2, varscan2
- ABCC10 | c.3319C>T p.L1107= (on ENST00000372530 / NM_001198934.2; = p.L1079= on NM_033450.2 and 1 other RefSeq transcript) | Silent (SNP) | VAF 7/52 reads (13%) | catalogued as COSV99767032; called by muse, mutect2, varscan2
- ALPK3 | c.877C>T p.L293= | Silent (SNP) | VAF 6/52 reads (12%) | catalogued as COSV99360644; called by mutect2, varscan2
- ANK2 | c.10044C>A p.L3348= | Silent (SNP) | VAF 9/45 reads (20%) | catalogued as COSV100000843, COSV52189247; called by muse, mutect2, varscan2
- AP002748.5 | c.1209C>G p.V403= | Silent (SNP) | VAF 8/51 reads (16%) | catalogued as COSV100567839; called by muse, mutect2, varscan2
- ASAP3 | c.1443C>G p.L481= | Silent (SNP) | VAF 4/15 reads (27%) | catalogued as COSV100369342; called by muse, mutect2
- ATP2C1 | c.2184T>G p.P728= | Silent (SNP) | VAF 16/86 reads (19%) | catalogued as COSV100146561; called by muse, mutect2, varscan2
- AWAT1 | c.522C>A p.L174= | Silent (SNP) | VAF 15/135 reads (11%) | catalogued as COSV100997193, COSV65738413; called by muse, mutect2, varscan2
- BRINP3 | c.2004G>T p.V668= | Silent (SNP) | VAF 12/83 reads (14%) | catalogued as COSV100818619; called by muse, mutect2, varscan2
- CCDC92 | c.132G>C p.T44= | Silent (SNP) | VAF 13/97 reads (13%) | catalogued as rs750311683, COSV53019217, COSV99435415; called by muse, varscan2
- CNOT8 | c.225C>T p.I75= | Silent (SNP) | VAF 10/52 reads (19%) | catalogued as COSV99597158; called by muse, mutect2, varscan2
- COL24A1 | c.969T>G p.S323= | Silent (SNP) | VAF 15/84 reads (18%) | catalogued as COSV100993132; called by muse, mutect2, varscan2
- DNAH7 | c.9399G>A p.L3133= | Silent (SNP) | VAF 14/68 reads (21%) | catalogued as COSV100414638; called by muse, mutect2, varscan2
- DOCK6 | c.5109G>A p.V1703= | Silent (SNP) | VAF 6/35 reads (17%) | catalogued as COSV99625258; called by muse, mutect2, varscan2
- ELFN2 | c.1014C>T p.T338= | Silent (SNP) | VAF 10/165 reads (6%) | catalogued as COSV101297521; called by muse, mutect2
- EPC1 | c.2373G>A p.L791= | Silent (SNP) | VAF 25/133 reads (19%) | catalogued as COSV99552792; called by muse, mutect2, varscan2
- EPHB6 | c.2976G>A p.L992= | Silent (SNP) | VAF 10/108 reads (9%) | catalogued as COSV100844233; called by muse, mutect2
- FOXM1 | c.969G>A p.V323= | Silent (SNP) | VAF 5/46 reads (11%) | catalogued as COSV100700825; called by mutect2, varscan2
- FSTL3 | c.663G>A p.S221= | Silent (SNP) | VAF 8/34 reads (24%) | catalogued as rs377720232, COSV99383844; called by mutect2, varscan2
- GPR63 | c.1207C>A p.R403= | Silent (SNP) | VAF 4/32 reads (13%) | catalogued as COSV100013248, COSV100013486; called by mutect2, varscan2
- GUCY2C | c.2472A>G p.T824= | Silent (SNP) | VAF 8/37 reads (22%) | catalogued as COSV99663480; called by muse, mutect2, varscan2
- H2AW | c.351G>A p.L117= | Silent (SNP) | VAF 16/80 reads (20%) | catalogued as COSV100797267; called by muse, mutect2, varscan2
- HDLBP | c.2226C>G p.L742= | Silent (SNP) | VAF 20/106 reads (19%) | catalogued as COSV100190287; called by muse, varscan2
- HECW2 | c.2763C>G p.P921= | Silent (SNP) | VAF 25/93 reads (27%) | catalogued as rs781631738, COSV99646682; called by muse, mutect2, varscan2
- IGHV3OR16-8 | c.93A>T p.V31= | Silent (SNP) | VAF 36/175 reads (21%) | called by muse, mutect2, varscan2
- IGHV6-1 | c.129C>A p.A43= | Silent (SNP) | VAF 7/52 reads (13%) | called by muse, mutect2, varscan2
- IGLC7 | c.291G>A p.E97= | Silent (SNP) | VAF 10/55 reads (18%) | called by muse, mutect2, varscan2
- INSRR | c.2970T>C p.F990= | Silent (SNP) | VAF 12/40 reads (30%) | catalogued as COSV100947344; called by muse, mutect2, varscan2
- KLHDC4 | c.1506C>G p.G502= | Silent (SNP) | VAF 10/64 reads (16%) | catalogued as COSV54507283, COSV99566263; called by muse, mutect2, varscan2
- KNTC1 | c.1824G>C p.V608= | Silent (SNP) | VAF 7/58 reads (12%) | catalogued as COSV100338162; called by muse, mutect2, varscan2
- KRT25 | c.753G>A p.L251= | Silent (SNP) | VAF 14/63 reads (22%) | catalogued as COSV100379877; called by muse, mutect2, varscan2
- KRTAP27-1 | c.216C>T p.D72= | Silent (SNP) | VAF 14/72 reads (19%) | catalogued as rs376929358, COSV101239699; called by muse, mutect2, varscan2
- LRP2 | c.5283T>C p.L1761= | Silent (SNP) | VAF 14/74 reads (19%) | catalogued as rs1423384566; called by muse, mutect2, varscan2
- MAMDC2 | c.1083C>A p.T361= | Silent (SNP) | VAF 27/140 reads (19%) | catalogued as rs771986746, COSV101015403; called by muse, mutect2, varscan2
- MARCHF11 | c.987C>T p.D329= | Silent (SNP) | VAF 12/48 reads (25%) | catalogued as rs764612045, COSV100197701; called by muse, mutect2, varscan2
- MED12 | c.322C>A p.R108= | Silent (SNP) | VAF 20/45 reads (44%) | catalogued as COSV100377193; called by muse, mutect2, varscan2
- MGAM | c.1083A>G p.Q361= | Silent (SNP) | VAF 8/94 reads (9%) | catalogued as COSV101527439; called by muse, mutect2
- MRPL45 | c.273T>A p.P91= | Silent (SNP) | VAF 12/83 reads (14%) | called by muse, mutect2, varscan2
- MUS81 | c.1131C>G p.L377= | Silent (SNP) | VAF 6/50 reads (12%) | catalogued as COSV100337216; called by muse, varscan2
- MYH10 | c.3771C>T p.L1257= | Silent (SNP) | VAF 6/61 reads (10%) | catalogued as rs780658326, COSV99344798; called by mutect2, varscan2
- NAT8 | c.306G>C p.L102= | Silent (SNP) | VAF 14/91 reads (15%) | catalogued as COSV99721970; called by muse, mutect2, varscan2
- NF1 | c.2983C>T p.L995= | Silent (SNP) | VAF 19/90 reads (21%) | catalogued as COSV100646606; called by muse, mutect2, varscan2
- NR0B1 | c.240C>G p.L80= | Silent (SNP) | VAF 5/26 reads (19%) | catalogued as COSV66763994, COSV66764157; called by muse, mutect2, varscan2
- NR4A1 | c.774G>T p.G258= | Silent (SNP) | VAF 12/76 reads (16%) | catalogued as rs746689109, COSV99671183; called by muse, mutect2, varscan2
- OLFM4 | c.1407T>A p.I469= | Silent (SNP) | VAF 15/46 reads (33%) | catalogued as rs1566321607, COSV99524266; called by muse, mutect2, varscan2
- OPN4 | c.975C>T p.H325= | Silent (SNP) | VAF 8/56 reads (14%) | catalogued as rs199918331, COSV54119228, COSV99618209; called by muse, mutect2
- OR10H2 | c.630C>G p.G210= | Silent (SNP) | VAF 7/87 reads (8%) | catalogued as COSV100008714; called by muse, mutect2
- OR2M3 | c.516G>T p.R172= | Silent (SNP) | VAF 28/153 reads (18%) | catalogued as COSV101513416, COSV71759372; called by muse, mutect2, varscan2
- OR52H1 | c.447C>T p.G149= (on ENST00000322653; = p.G155= on NM_001005289.1) | Silent (SNP) | VAF 6/25 reads (24%) | catalogued as rs931568596, COSV100497295; called by muse, mutect2, varscan2
- OR6C65 | c.687C>T p.A229= | Silent (SNP) | VAF 11/84 reads (13%) | catalogued as COSV101110179; called by mutect2, varscan2
- OSM | c.6G>T p.G2= | Silent (SNP) | VAF 13/45 reads (29%) | catalogued as COSV99304104; called by muse, mutect2, varscan2
- PAPPA2 | c.3231G>C p.T1077= | Silent (SNP) | VAF 24/168 reads (14%) | catalogued as COSV62792179, COSV62811799; called by muse, mutect2, varscan2
- PAXBP1 | c.1743C>T p.S581= | Silent (SNP) | VAF 15/57 reads (26%) | catalogued as rs140333561; called by muse, mutect2, varscan2
- PCDH11X | c.4017C>A p.S1339= | Silent (SNP) | VAF 14/89 reads (16%) | catalogued as COSV53445084; called by muse, mutect2, varscan2
- PCDHB5 | c.1614G>T p.P538= | Silent (SNP) | VAF 11/34 reads (32%) | catalogued as COSV50657271, COSV99167804; called by muse, mutect2, varscan2
- PCLO | c.12651A>C p.S4217= | Silent (SNP) | VAF 6/29 reads (21%) | catalogued as COSV100430322; called by muse, mutect2, varscan2
- PGAP1 | c.18T>G p.V6= | Silent (SNP) | VAF 13/195 reads (7%) | catalogued as COSV100698117; called by muse, mutect2
- PIK3CG | c.678C>G p.R226= | Silent (SNP) | VAF 13/126 reads (10%) | catalogued as COSV100782772; called by muse, mutect2, varscan2
- PRICKLE3 | c.507G>T p.L169= | Silent (SNP) | VAF 5/27 reads (19%) | catalogued as COSV100889906; called by muse, mutect2, varscan2
- PRRG3 | c.276G>C p.L92= | Silent (SNP) | VAF 35/170 reads (21%) | catalogued as COSV100948588; called by muse, mutect2, varscan2
- PTGER4 | c.459G>T p.L153= | Silent (SNP) | VAF 17/64 reads (27%) | catalogued as COSV100201502; called by muse, mutect2, varscan2
- RAB5C | c.237A>T p.G79= | Silent (SNP) | VAF 14/78 reads (18%) | catalogued as rs1420834435, COSV100651398; called by muse, mutect2, varscan2
- RAET1G | c.282G>C p.L94= | Silent (SNP) | VAF 24/150 reads (16%) | catalogued as COSV100951655, COSV66275194; called by muse, mutect2, varscan2
- RASGRF1 | c.2172C>T p.Y724= | Silent (SNP) | VAF 20/62 reads (32%) | catalogued as rs770172047, COSV101174436; ClinVar: likely benign; called by muse, mutect2, varscan2
- REXO5 | c.1563G>A p.L521= | Silent (SNP) | VAF 14/89 reads (16%) | catalogued as rs1158962182, COSV99759085; called by muse, mutect2, varscan2
- RP1 | c.5322C>A p.T1774= | Silent (SNP) | VAF 6/36 reads (17%) | catalogued as COSV99606985; called by muse, mutect2, varscan2
- SLC6A11 | c.456A>T p.A152= | Silent (SNP) | VAF 25/105 reads (24%) | catalogued as COSV99594344; called by muse, mutect2, varscan2
- SLC7A3 | c.840C>A p.P280= | Silent (SNP) | VAF 15/49 reads (31%) | catalogued as COSV99979482; called by muse, mutect2, varscan2
- SMIM8 | c.174A>T p.S58= | Silent (SNP) | VAF 8/86 reads (9%) | catalogued as COSV99994709; called by muse, mutect2
- TEX10 | c.1462A>C p.R488= | Silent (SNP) | VAF 18/76 reads (24%) | catalogued as COSV100887680; called by muse, mutect2, varscan2
- TMEM200C | c.1621C>A p.R541= | Silent (SNP) | VAF 10/44 reads (23%) | catalogued as rs1280267248, COSV101274809, COSV67309191; called by muse, mutect2, varscan2
- TPR | c.1989A>G p.T663= | Silent (SNP) | VAF 15/111 reads (14%) | catalogued as COSV100823793; called by muse, mutect2, varscan2
- TTN | c.16755G>C p.G5585= (on ENST00000591111; = p.G4658= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 37/228 reads (16%) | catalogued as COSV100604316; called by muse, mutect2, varscan2
- USH2A | c.11124C>A p.P3708= | Silent (SNP) | VAF 12/94 reads (13%) | catalogued as COSV100232572; called by muse, mutect2, varscan2
- UTRN | c.2091A>G p.A697= | Silent (SNP) | VAF 7/30 reads (23%) | catalogued as COSV100839782; called by muse, mutect2, varscan2
- VN1R4 | c.717G>A p.V239= | Silent (SNP) | VAF 4/17 reads (24%) | catalogued as COSV100237388; called by muse, mutect2, varscan2
- WDR17 | c.3783G>A p.V1261= | Silent (SNP) | VAF 5/47 reads (11%) | catalogued as rs1358349674, COSV99707310; called by muse, mutect2, varscan2
- XKRX | c.765C>T p.L255= | Silent (SNP) | VAF 5/47 reads (11%) | catalogued as COSV100139634; called by mutect2, varscan2
- ZNF331 | c.549G>T p.G183= | Silent (SNP) | VAF 15/108 reads (14%) | catalogued as COSV53476025, COSV99467131; called by muse, mutect2, varscan2
- ZNF665 | c.1590A>G p.E530= (on ENST00000600412; = p.E595= on NM_024733.5 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 14/100 reads (14%) | catalogued as COSV101128195; called by muse, mutect2, varscan2
- AL590867.2 | n.154T>C | RNA (SNP) | VAF 19/127 reads (15%) | called by muse, mutect2, varscan2
- MAGEC3 | c.1729-55C>T | Intron (SNP) | VAF 7/55 reads (13%) | catalogued as rs891995647, COSV100025175; called by muse, mutect2, varscan2
- MIR196A1 | n.23G>T | RNA (SNP) | VAF 13/43 reads (30%) | catalogued as rs190478598; called by muse, varscan2
- NEBL | c.164+25925A>G | Intron (SNP) | VAF 16/68 reads (24%) | catalogued as COSV101008760; called by muse, mutect2, varscan2
- RNF213 | c.3024+142G>T | Intron (SNP) | VAF 13/47 reads (28%) | catalogued as COSV100173337, COSV100174021; called by muse, mutect2, varscan2
- SNORD115-15 | n.67A>G | RNA (SNP) | VAF 43/240 reads (18%) | called by muse, mutect2, varscan2
- SSX7 | c.-2C>G | 5'UTR (SNP) | VAF 42/234 reads (18%) | catalogued as COSV99993792; called by muse, varscan2
